Gene-level copy-number profile of tumor specimen TCGA-75-7027-01A from TCGA case TCGA-75-7027, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB.
Specimen TCGA-75-7027-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.068f2bd9-573a-4a8c-a086-fa8eee1b54dc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-75-7027-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a320c21e-c3f3-41ab-9a8c-914a31f8e843

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 153; copy number 2: 23,504; copy number 3: 17,401; copy number 4: 2,457; copy number 5: 7,258; copy number 6: 9,037.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-75-7027-01A-11D-1943-01): tumor purity 0.62, ploidy 3.09, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 16,295 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,603 genes, copy number 5–6 (broad region; genes not listed).
- chr2:38,814–235,055,714, 4,032 genes, copy number 6 (broad region; genes not listed).
- chr2:236,037,250–242,160,153, 157 genes, copy number 5 (broad region; genes not listed).
- chr4:49,096–52,551,574, 758 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr8:150,584–145,066,685, 2,481 genes, copy number 5 (broad region; genes not listed).
- chr10:65,570,338–133,761,125, 1,294 genes, copy number 5 (broad region; genes not listed).
- chr12:66,767–105,744,062, 2,308 genes, copy number 5–6 (broad region; genes not listed).
- chr12:109,445,410–114,412,831, 130 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 5 (broad region; genes not listed).
- chr16:46,469,341–90,222,851, 1,141 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 153. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
